Somatic mutation profile of tumor specimen MMRF_1401_1_BM_CD138pos (aliquot MMRF_1401_1_BM_CD138pos_T1_KAS5U_L01921) from MMRF case MMRF_1401, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 82.9 years (30,263 days).
Specimen MMRF_1401_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14d619a8-1c9d-41ee-9cb2-e156bdc9be1e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1401_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1401_1_PB_Whole_C2_KAS5U_L01932; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d057ff45-b849-4205-87e2-c671f9dbf7b1

The open-access MAF lists 96 somatic variants for this specimen: 37 protein-altering or splice-affecting, 6 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, 3'UTR 30, Intron 13, 5'UTR 8, Silent 6, 5'Flank 2, Nonsense Mutation 2, Frame Shift Ins 1, Frame Shift Del 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 66/70 reads (94%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, varscan2
- C9orf152 | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 20/362 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs138966973; called by muse, mutect2
- FAM117B | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 145/269 reads (54%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.883); catalogued as rs774669794, COSV57419630; called by muse, mutect2, varscan2
- IGHV2-70 | c.321C>G p.D107E | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1274128035; called by muse, varscan2
- IGLV4-60 | c.151A>T p.S51C | Missense Mutation (SNP) | VAF 90/95 reads (95%) | SIFT tolerated (0.05); PolyPhen benign (0.071); catalogued as rs536416304; called by muse, mutect2, varscan2
- LRRC7 | c.4359G>T p.Q1453H (on ENST00000651989 / NM_001370785.2; = p.Q1373H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV99224388; called by mutect2, varscan2
- MAGEL2 | c.3158A>T p.E1053V | Missense Mutation (SNP) | VAF 72/140 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as rs765345034; called by muse, mutect2, varscan2
- MAIP1 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99705331; called by muse, mutect2, varscan2
- MEGF8 | c.8368G>A p.G2790R (on ENST00000251268 / NM_001271938.2; = p.G2723R on NM_001410.3) | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776276340, COSV52096959; called by muse, varscan2
- MLH1 | c.2162A>C p.Y721S | Missense Mutation (SNP) | VAF 74/486 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as rs587778986; called by muse, mutect2, varscan2
- PGM1 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs754131603, COSV64300610; called by muse, mutect2, varscan2
- SHISA3 | c.271A>G p.T91A | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1454272136; called by muse, mutect2, varscan2
- SLITRK3 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV53846738; called by muse, mutect2
- UNC93B1 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as rs752295686; called by muse, mutect2, varscan2
- ZKSCAN1 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs1355735435; called by muse, mutect2, varscan2
- ABCA1 | c.4445G>T p.G1482V | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABI1 | c.56T>G p.L19R | Missense Mutation (SNP) | VAF 129/260 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APBA1 | c.1337-2A>G p.X446_splice | Splice Site (SNP) | VAF 37/114 reads (32%) | called by muse, mutect2, varscan2
- CD44 | c.1649C>G p.S550C | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CDHR2 | c.1268C>G p.A423G | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- COL6A5 | c.4291G>A p.G1431R | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUSP7 | c.1104_1114dup p.F372Sfs*20 | Frame Shift Ins (INS) | VAF 48/126 reads (38%) | called by mutect2, varscan2
- FAM124A | c.787G>C p.G263R (on ENST00000322475 / NM_001242312.2; = p.G299R on NM_145019.4) | Missense Mutation (SNP) | VAF 77/140 reads (55%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FREM1 | c.2790_2793del p.R932Nfs*7 | Frame Shift Del (DEL) | VAF 71/214 reads (33%) | called by mutect2, pindel, varscan2
- FREM2 | c.1772C>A p.S591* | Nonsense Mutation (SNP) | VAF 47/88 reads (53%) | called by muse, mutect2, varscan2
- HTR3C | c.1015C>G p.Q339E | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- IGLV1-51 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 23/23 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, varscan2
- IGSF10 | c.6110C>G p.P2037R | Missense Mutation (SNP) | VAF 173/351 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ITGAX | c.958G>C p.D320H | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- NOTCH3 | c.5341G>A p.D1781N | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- NTRK2 | c.1081C>G p.L361V | Missense Mutation (SNP) | VAF 99/294 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR8B8 | c.807_809del p.N269_Q270delinsK | In Frame Del (DEL) | VAF 97/344 reads (28%) | called by mutect2, pindel, varscan2
- PCDHA6 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 50/86 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PGM2L1 | c.410T>C p.V137A | Missense Mutation (SNP) | VAF 129/489 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- PKN3 | c.2530G>A p.D844N | Missense Mutation (SNP) | VAF 64/223 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRDM15 | c.2159A>T p.Y720F | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ZNF568 | c.1208C>G p.S403* | Nonsense Mutation (SNP) | VAF 40/112 reads (36%) | called by muse, mutect2, varscan2
- IQUB | c.1402T>C p.L468= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as rs1296002931; called by muse, mutect2, varscan2
- NCS1 | c.321C>G p.L107= | Silent (SNP) | VAF 40/159 reads (25%) | called by muse, varscan2
- NFXL1 | c.2193G>A p.Q731= | Silent (SNP) | VAF 70/158 reads (44%) | called by muse, mutect2, varscan2
- PRDM13 | c.186C>T p.G62= | Silent (SNP) | VAF 20/57 reads (35%) | called by muse, mutect2
- STARD9 | c.660C>T p.A220= | Silent (SNP) | VAF 96/203 reads (47%) | catalogued as rs1206410526; called by muse, mutect2, varscan2
- THBD | c.126C>T p.P42= | Silent (SNP) | VAF 29/70 reads (41%) | called by muse, mutect2, varscan2
- ADGRF1 | c.2593-28C>T | Intron (SNP) | VAF 9/89 reads (10%) | called by muse, mutect2
- ADM2 | c.-11-9C>T | Intron (SNP) | VAF 21/40 reads (53%) | catalogued as rs771526212; called by muse, mutect2, varscan2
- ALG6 | c.817-57G>T | Intron (SNP) | VAF 16/28 reads (57%) | called by muse, mutect2, varscan2
- ANKHD1 | c.-135A>T | 5'UTR (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2, varscan2
- BAIAP2 | c.1535+679C>T | Intron (SNP) | VAF 39/62 reads (63%) | catalogued as rs1378303543; called by muse, mutect2, varscan2
- BEST3 | c.*8A>G | 3'UTR (SNP) | VAF 177/386 reads (46%) | called by muse, mutect2, varscan2
- CAPRIN2 | c.-591G>A | 5'UTR (SNP) | VAF 161/315 reads (51%) | called by muse, mutect2, varscan2
- CD164 | c.*407A>G | 3'UTR (SNP) | VAF 62/121 reads (51%) | catalogued as rs575312893; called by muse, mutect2, varscan2
- CHRNB1 | c.462+44C>T | Intron (SNP) | VAF 119/239 reads (50%) | called by muse, mutect2, varscan2
- CNPY2 | c.-25-176G>A | Intron (SNP) | VAF 6/12 reads (50%) | called by muse, varscan2
- COA1 | c.-38-489A>C | Intron (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- CPNE3 | c.*1430A>T | 3'UTR (SNP) | VAF 7/145 reads (5%) | called by muse, mutect2
- CREBRF | c.*3517G>C | 3'UTR (SNP) | VAF 77/168 reads (46%) | called by muse, mutect2, varscan2
- CREBRF | c.*4249G>C | 3'UTR (SNP) | VAF 40/82 reads (49%) | called by muse, varscan2
- CREBRF | c.*4575_*4578delinsATTA | 3'UTR (ONP) | VAF 18/121 reads (15%) | called by muse*, pindel
- CREBRF | c.*4750G>T | 3'UTR (SNP) | VAF 40/95 reads (42%) | called by muse, mutect2, varscan2
- CREBRF | c.*5340G>A | 3'UTR (SNP) | VAF 49/108 reads (45%) | called by mutect2, varscan2
- CUX1 | c.*6574G>C | 3'UTR (SNP) | VAF 10/68 reads (15%) | catalogued as rs1294743426; called by muse, mutect2, varscan2
- DACH2 | c.1751-519A>C | Intron (SNP) | VAF 59/62 reads (95%) | called by muse, mutect2, varscan2
- DAND5 | c.*25G>A | 3'UTR (SNP) | VAF 40/69 reads (58%) | catalogued as rs375137580; called by muse, mutect2, varscan2
- FAM13A | c.605+34A>C | Intron (SNP) | VAF 55/118 reads (47%) | called by muse, mutect2, varscan2
- FAM98B | c.*1470A>G | 3'UTR (SNP) | VAF 37/66 reads (56%) | called by muse, mutect2, varscan2
- GABRA4 | c.*5426T>C | 3'UTR (SNP) | VAF 65/151 reads (43%) | called by muse, mutect2, varscan2
- GLB1L2 | c.*523T>A | 3'UTR (SNP) | VAF 85/220 reads (39%) | called by muse, mutect2, varscan2
- GMCL1 | c.*1643G>A | 3'UTR (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2
- GORAB | c.662+369G>T | Intron (SNP) | VAF 35/61 reads (57%) | called by muse, mutect2, varscan2
- KLF4 | c.-10C>A | 5'UTR (SNP) | VAF 45/145 reads (31%) | called by muse, mutect2, varscan2
- KRBA2 | c.*203G>A | 3'UTR (SNP) | VAF 25/53 reads (47%) | catalogued as rs549192093; called by muse, mutect2, varscan2
- MAGT1 | c.*1775A>G | 3'UTR (SNP) | VAF 8/10 reads (80%) | catalogued as rs1025622223; called by mutect2, varscan2
- MED8 | c.*491C>A | 3'UTR (SNP) | VAF 31/212 reads (15%) | called by mutect2, varscan2
- MEGF10 | c.*2239G>C | 3'UTR (SNP) | VAF 6/68 reads (9%) | catalogued as rs1371177070; called by muse, mutect2
- MTHFD2 | chr2:74198614 C>G | 5'Flank (SNP) | VAF 31/77 reads (40%) | catalogued as rs112453409; called by muse, mutect2, varscan2
- NR2F1 | c.-1047C>T | 5'UTR (SNP) | VAF 65/67 reads (97%) | called by muse, mutect2, varscan2
- PFAS | c.*213G>T | 3'UTR (SNP) | VAF 65/128 reads (51%) | catalogued as rs915376771; called by muse, mutect2, varscan2
- PGA5 | c.657-206C>A | Intron (SNP) | VAF 32/364 reads (9%) | catalogued as rs760628230; called by muse, mutect2
- PGRMC2 | c.*1024G>A | 3'UTR (SNP) | VAF 63/117 reads (54%) | called by muse, mutect2, varscan2
- PIK3CD | c.-138+2699C>T | Intron (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- PLEKHH2 | c.*1887G>A | 3'UTR (SNP) | VAF 37/95 reads (39%) | catalogued as rs1008440189; called by muse, mutect2, varscan2
- PLXNA4 | c.*6041C>G | 3'UTR (SNP) | VAF 96/224 reads (43%) | called by muse, varscan2
- PPP3CA | c.-337G>C | 5'UTR (SNP) | VAF 84/201 reads (42%) | called by mutect2, varscan2
- PXDC1 | c.-119G>A | 5'UTR (SNP) | VAF 13/27 reads (48%) | called by mutect2, varscan2
- RAET1E | c.622+213C>A | Intron (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
- RBMXL1 | c.*2032G>A | 3'UTR (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- RCOR1 | c.*1265A>G | 3'UTR (SNP) | VAF 41/81 reads (51%) | called by muse, mutect2, varscan2
- SLAMF1 | chr1:160647066 C>T | 5'Flank (SNP) | VAF 27/87 reads (31%) | called by muse, mutect2, varscan2
- SLC6A2 | c.*1340G>A | 3'UTR (SNP) | VAF 24/43 reads (56%) | called by muse, mutect2, varscan2
- SNAP23 | c.*147T>G | 3'UTR (SNP) | VAF 32/89 reads (36%) | called by muse, mutect2, varscan2
- SNX21 | c.*729A>G | 3'UTR (SNP) | VAF 72/148 reads (49%) | called by muse, mutect2, varscan2
- SPG21 | c.*112C>A | 3'UTR (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
- SSBP2 | c.-10C>T | 5'UTR (SNP) | VAF 103/235 reads (44%) | catalogued as rs745699701; called by muse, mutect2, varscan2
- TMEM184C | c.-552C>G | 5'UTR (SNP) | VAF 31/80 reads (39%) | called by muse, mutect2, varscan2
- ZC3H7A | c.*602C>G | 3'UTR (SNP) | VAF 59/128 reads (46%) | catalogued as rs990318293, COSV100865632; called by muse, mutect2, varscan2
- ZC3H7A | c.*463C>G | 3'UTR (SNP) | VAF 56/114 reads (49%) | called by muse, mutect2, varscan2
